Gene-level copy-number profile of tumor specimen ALCH-B24N-TTP1-A from ALCHEMIST case ALCH-B24N, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.7 years (24,716 days).
Specimen ALCH-B24N-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 18f95982-0502-460c-91ff-bf8718da8f1c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B24N-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,221 have no estimate.
https://portal.gdc.cancer.gov/files/a54bf5f0-61ea-4e0d-a3a7-63c2bd54a579

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 273; copy number 2: 55,004; copy number 3: 3,101; copy number 4: 7; copy number 5: 1; copy number 7: 1.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,242,446–1,246,722, 1 gene: C1QTNF12.
- chr4:1,009,936–1,026,898, 1 gene: FGFRL1.
- chr8:12,095,176–12,099,536, 1 gene: DEFB108D.
- chr11:612,553–627,181, 3 genes: IRF7, CDHR5, SCT.
- chr14:18,614,388–18,633,634, 3 genes (within-gene range 0–2): CR383656.6, ARHGAP42P5, LINC02297.
- chr14:18,634,955–18,637,421, 2 genes (within-gene range 0–2): CR383656.1, CR383656.12.
- chr18:31,937,533–31,967,545, 4 genes (within-gene range 0–2): RNU6-1050P, AC009831.1, PGDP1, AC009831.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,249,777–1,251,334, 1 gene, copy number 5: AL162741.1.
- chr21:8,680,538–8,680,934, 1 gene, copy number 7: CR381572.2.

Autosomal genes at a single copy (total copy number 1): 273. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
